EXCEPTIONAL_RESPONDERS case ER-AEK6 — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f8684ef1-bfef-4975-b1ae-b7085b11c1f8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1934; Vital status: Alive.

Diagnoses (2)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.2 years (24,162 days); AJCC pathologic stage: Stage I.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Unknown primary site; Age at diagnosis: 74.1 years (27,083 days); Year of diagnosis: 2009; AJCC staging edition: 7th; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Days to last follow up: 2,685 days (7.4 years); Days to best overall response: 1,466 days (4.0 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 56 days; Days to treatment end: 413 days (1.1 years).

Follow-up (1 entry)
- Days to follow up: 2,685 days (7.4 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 2,685 days (7.4 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AEK6-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AEK6-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-AEK6-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AEK6-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 5; Percent tumor nuclei: 8; Percent normal cells: 85; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
